Somatic mutation profile of tumor specimen TCGA-DA-A3F5-06A (aliquot TCGA-DA-A3F5-06A-11D-A20D-08) from TCGA case TCGA-DA-A3F5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 62.2 years (22,720 days).
Specimen TCGA-DA-A3F5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27bacc82-e861-4641-945d-3e1335439c0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A3F5-10A (Blood Derived Normal), aliquot TCGA-DA-A3F5-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b114eacd-5ae1-4805-9c3c-5d0097235ad4

The open-access MAF lists 391 somatic variants for this specimen: 266 protein-altering or splice-affecting, 114 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 229, Silent 114, Nonsense Mutation 18, Splice Site 10, Splice Region 7, Intron 4, RNA 4, 5'UTR 1, In Frame Del 1, 3'UTR 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/147 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CHD2 | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 9/119 reads (8%) | catalogued as rs1567138301, COSV59119573; ClinVar: pathogenic; called by muse, mutect2
- SACS | c.9305T>A p.L3102* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as rs886041949, COSV66537749; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.5207C>T p.S1736F (on ENST00000614293; = p.S1706F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV55799576; called by muse, mutect2, varscan2
- ABCA4 | c.1897T>A p.Y633N | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV64671912; called by muse, mutect2, varscan2
- ABCD3 | c.915T>G p.N305K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64642702; called by muse, mutect2, varscan2
- ABCG8 | c.1756+1G>A p.X586_splice | Splice Site (SNP) | VAF 19/56 reads (34%) | catalogued as rs1316023527, COSV55391824; called by muse, mutect2, varscan2
- ABO | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71743488; called by muse, mutect2, varscan2
- ACSM1 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs138822345; called by muse, mutect2, varscan2
- ADCY9 | c.3829G>A p.E1277K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53572768; called by muse, mutect2, varscan2
- ADGRB3 | c.2180G>A p.G727E | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV65390232; called by muse, mutect2, varscan2
- AHNAK2 | c.2801C>T p.P934L | Missense Mutation (SNP) | VAF 154/290 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60911739; called by muse, mutect2, varscan2
- AHSP | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as COSV56528702; called by muse, mutect2, varscan2
- AKR1C3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV65910240; called by muse, mutect2, varscan2
- AKT2 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV60907953; called by muse, mutect2, varscan2
- ALDH1L2 | c.1755C>T p.L585= | Splice Region (SNP) | VAF 44/314 reads (14%) | catalogued as rs757516453, COSV51554523; called by muse, mutect2, varscan2
- ANGPT4 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1230184668, COSV67920970; called by muse, mutect2, varscan2
- ANKFN1 | c.2108A>G p.N703S | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV59443194; called by muse, mutect2, varscan2
- ANKRD46 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 77/114 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs267601678, COSV59513939, COSV59514594; called by muse, mutect2, varscan2
- ANO4 | c.181C>T p.L61F (on ENST00000392977 / NM_001286615.2; = p.L26F on NM_178826.4) | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV54589191; called by muse, mutect2, varscan2
- ARAP2 | c.5077C>T p.L1693F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV58284782; called by muse, mutect2, varscan2
- ARL6IP1 | c.169del p.L57* | Frame Shift Del (DEL) | VAF 16/110 reads (15%) | catalogued as COSV58614158, COSV58614466; called by mutect2, pindel, varscan2
- ARPC2 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as COSV55283918; called by muse, mutect2, varscan2
- ASXL3 | c.6301G>T p.V2101F | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV52462118; called by muse, mutect2, varscan2
- ATP8B4 | c.1474C>T p.Q492* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV52712244; called by muse, mutect2, varscan2
- BCL9 | c.1918C>G p.Q640E | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV52342557; called by muse, mutect2, varscan2
- BMP6 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51662298; called by muse, mutect2, varscan2
- BPTF | c.977G>A p.W326* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | catalogued as COSV58833553; called by muse, mutect2, varscan2
- BSDC1 | c.357+1G>T p.X119_splice | Splice Site (SNP) | VAF 17/68 reads (25%) | catalogued as COSV61981549; called by muse, mutect2, varscan2
- BTBD11 | c.2196G>A p.M732I (on ENST00000280758 / NM_001018072.2; = p.M269I on NM_001017523.2) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV55019873; called by mutect2, varscan2
- C1R | c.1459G>A p.G487S (on ENST00000536053 / NM_001354346.2; = p.G473S on NM_001733.7) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV73382874; called by muse, mutect2
- C3orf20 | c.2365G>A p.G789R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs766336867, COSV53783344; called by muse, mutect2, varscan2
- C3orf56 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV67756126, COSV67756496; called by muse, mutect2, varscan2
- CACNB4 | c.390G>A p.E130= | Splice Region (SNP) | VAF 6/19 reads (32%) | catalogued as COSV52391512; called by muse, mutect2, varscan2
- CACNG6 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV104373907, COSV53166225; called by muse, mutect2, varscan2
- CC2D2B | c.685A>G p.T229A | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60357555; called by muse, mutect2, varscan2
- CCDC137 | c.497+1G>A p.X166_splice | Splice Site (SNP) | VAF 17/28 reads (61%) | catalogued as rs201831605; called by muse, mutect2, varscan2
- CCDC54 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV53758288; called by muse, mutect2, varscan2
- CD1E | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV63770534, COSV63771210; called by muse, mutect2, varscan2
- CDC42EP1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 111/257 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.879); catalogued as COSV50755812; called by muse, mutect2, varscan2
- CDH18 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56908981; called by muse, mutect2, varscan2
- CDH9 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50258116; called by muse, mutect2, varscan2
- CDON | c.83C>G p.A28G | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV54996488, COSV55000271; called by muse, mutect2, varscan2
- CDR2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV51675564; called by muse, mutect2, varscan2
- CECR2 | c.3737C>A p.P1246Q (on ENST00000342247 / NM_001290047.2; = p.P1062Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.621); catalogued as COSV52838825; called by muse, mutect2, varscan2
- CELSR1 | c.5413-1G>A p.X1805_splice | Splice Site (SNP) | VAF 46/80 reads (58%) | catalogued as COSV53085736; called by muse, mutect2, varscan2
- CFAP57 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1397955249, COSV65263962; called by muse, mutect2, varscan2
- CFTR | c.2912G>A p.G971E | Missense Mutation (SNP) | VAF 122/209 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV50042068; called by muse, mutect2, varscan2
- CGN | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 25/48 reads (52%) | catalogued as rs867096498, COSV54969010; called by muse, mutect2, varscan2
- CHPF | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV60534191; called by muse, mutect2, varscan2
- CHRM4 | c.1436G>A p.R479K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as COSV58986683; called by muse, mutect2, varscan2
- CHRND | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV51317699; called by muse, mutect2, varscan2
- CLTC | c.2906C>T p.P969L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV52246339; called by muse, mutect2, varscan2
- CMSS1 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70435975; called by muse, mutect2, varscan2
- CMYA5 | c.10514A>T p.K3505I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV71404948; called by muse, mutect2
- CNGA2 | c.1051C>A p.L351I | Missense Mutation (SNP) | VAF 54/77 reads (70%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.472); catalogued as COSV61703834; called by muse, mutect2, varscan2
- CNPY2 | c.83G>C p.C28S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV56264045; called by muse, varscan2
- COL11A2 | c.1139G>A p.G380E (on ENST00000341947 / NM_080680.3; = p.G273E on NM_080679.2) | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59495119; called by muse, mutect2, varscan2
- COL14A1 | c.1375A>G p.M459V | Missense Mutation (SNP) | VAF 145/193 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV52849696; called by muse, mutect2, varscan2
- COL15A1 | c.2045G>A p.G682E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66642276; called by muse, mutect2, varscan2
- COL3A1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.9); catalogued as COSV58584191; called by muse, mutect2, varscan2
- COLEC11 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52592700; called by muse, mutect2, varscan2
- CSMD3 | c.9926A>G p.Y3309C (on ENST00000297405 / NM_001363185.1; = p.Y3140C on NM_052900.3) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52142337; called by muse, mutect2, varscan2
- CYP11A1 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs773145475, COSV51430875, COSV99165888; called by muse, mutect2, varscan2
- CYP2C18 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV53670583; called by muse, mutect2, varscan2
- DNAH5 | c.10054G>A p.E3352K | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV54207833; called by muse, mutect2, varscan2
- DNAH8 | c.1448T>A p.I483N | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59432261; called by muse, mutect2, varscan2
- DNAI1 | c.681G>A p.Q227= | Splice Region (SNP) | VAF 36/68 reads (53%) | catalogued as COSV54280003; called by muse, mutect2, varscan2
- DNAJA2 | c.899C>T p.P300L | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs760638193, COSV57694509; called by muse, mutect2, varscan2
- DOCK3 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as COSV56512589; called by muse, mutect2, varscan2
- DSC3 | c.1969G>A p.G657S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs778926352, COSV64572183; called by muse, mutect2, varscan2
- DSG4 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs763569094, COSV57388581, COSV57389351; called by muse, mutect2, varscan2
- DUSP16 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53806779; called by muse, mutect2, varscan2
- DUXA | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV73729575; called by muse, mutect2, varscan2
- DYRK4 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50538195; called by muse, mutect2, varscan2
- EGFLAM | c.2756C>T p.S919F (on ENST00000354891 / NM_001205301.2; = p.S911F on NM_152403.4) | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59297320; called by muse, mutect2, varscan2
- ELAPOR1 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as rs756426797, COSV64044590; called by muse, mutect2, varscan2
- ENTPD8 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 65/134 reads (49%) | catalogued as COSV58160908; called by muse, mutect2, varscan2
- EPDR1 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.084); catalogued as rs1356874338; called by muse, mutect2
- EPS15L1 | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV50167822; called by muse, mutect2, varscan2
- EXOC1 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV62119496; called by muse, mutect2, varscan2
- FABP2 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370366662; called by muse, mutect2
- FAM83B | c.2069G>T p.R690M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60920288; called by muse, mutect2, varscan2
- FASTKD5 | c.878A>T p.Q293L | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV53904724; called by muse, mutect2, varscan2
- FAT4 | c.11480C>T p.S3827F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV58675806; called by muse, mutect2, varscan2
- FBH1 | c.2783G>A p.R928H (on ENST00000362091 / NM_178150.3; = p.R979H on NM_032807.4) | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.87); catalogued as rs770675963, COSV62981956; called by muse, mutect2, varscan2
- FEM1C | c.1376T>A p.L459Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV57231011; called by muse, mutect2, varscan2
- FER1L6 | c.2716G>A p.D906N | Missense Mutation (SNP) | VAF 201/262 reads (77%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs201385745, COSV67549069; called by muse, mutect2, varscan2
- FLG2 | c.4766C>T p.S1589L | Missense Mutation (SNP) | VAF 164/337 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV66167281; called by muse, mutect2, varscan2
- FOXC2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV57443975; called by muse, mutect2, varscan2
- FZD8 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV65967694; called by muse, mutect2, varscan2
- GALNT14 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61103434; called by muse, mutect2, varscan2
- GALNT5 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV52036767; called by muse, mutect2, varscan2
- GOT2 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV55331129; called by muse, mutect2, varscan2
- GRM6 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs572341483, COSV51437893; called by mutect2, varscan2
- GRXCR2 | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV65060817; called by muse, mutect2, varscan2
- HMCN1 | c.13705C>T p.Q4569* | Nonsense Mutation (SNP) | VAF 31/53 reads (58%) | catalogued as COSV54885421; called by muse, mutect2, varscan2
- HMSD | c.85A>C p.S29R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as COSV68816862; called by muse, mutect2, varscan2
- HNRNPM | c.1069A>T p.M357L | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV57692088; called by muse, mutect2, varscan2
- HOOK1 | c.1795A>G p.M599V | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as rs983259900, COSV64618290; called by muse, mutect2
- HOXC11 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs773152809, COSV54532773, COSV54532802; called by muse, mutect2, varscan2
- HSPG2 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV65930110; called by muse, mutect2, varscan2
- HYDIN | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55480200; called by muse, mutect2, varscan2
- IGHV3-23 | c.10G>T p.G4W | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as rs976651167; called by muse, mutect2, varscan2
- IL1RL1 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.121); catalogued as COSV52114319, COSV52120872; called by muse, mutect2, varscan2
- IL1RN | c.502G>A p.V168I (on ENST00000409930 / NM_173842.3; = p.V150I on NM_000577.5) | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.84); PolyPhen benign (0.02); catalogued as COSV52080286; called by muse, mutect2, varscan2
- IL7R | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD1313328, COSV57405859; called by muse, mutect2, varscan2
- ILDR2 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV54829608; called by muse, mutect2, varscan2
- IQCK | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs376359131; called by muse, mutect2, varscan2
- ITPR1 | c.5396T>C p.L1799P (on ENST00000354582; = p.L1744P on NM_002222.7) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV56975490; called by muse, mutect2, varscan2
- ITPR3 | c.7613G>A p.C2538Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65268151; called by muse, mutect2, varscan2
- KCNH6 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368030494; called by muse, mutect2, varscan2
- KIF18B | c.2030G>C p.G677A (on ENST00000593135 / NM_001265577.2; = p.G689A on NM_001264573.2) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.82); PolyPhen benign (0.085); catalogued as COSV59271997; called by muse, mutect2, varscan2
- KLHL4 | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 19/29 reads (66%) | catalogued as COSV64140526; called by muse, mutect2, varscan2
- KPRP | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.457); catalogued as COSV64221224; called by muse, mutect2, varscan2
- KRT17 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV60860273; called by muse, mutect2, varscan2
- KRT34 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); catalogued as rs1239097466, COSV67449453; called by muse, mutect2, varscan2
- KRT9 | c.883-1G>A p.X295_splice | Splice Site (SNP) | VAF 59/99 reads (60%) | catalogued as COSV55851950; called by muse, mutect2, varscan2
- KRTAP5-5 | c.277G>C p.G93R | Missense Mutation (SNP) | VAF 85/250 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as COSV68784656, COSV68785101; called by muse, mutect2, varscan2
- KSR2 | c.1384C>T p.H462Y | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.162); catalogued as COSV56669484; called by muse, mutect2, varscan2
- LCT | c.2735C>T p.S912F | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51545740; called by muse, mutect2, varscan2
- LIX1 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1288073701, COSV57206437; called by muse, mutect2, varscan2
- LRP1B | c.4729C>T p.L1577F | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV67197912, COSV67221199; called by mutect2, varscan2
- LUC7L2 | c.1072T>G p.S358A | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.355); catalogued as COSV54924966; called by muse, mutect2, varscan2
- MAGEA12 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 108/156 reads (69%) | SIFT tolerated (0.18); PolyPhen benign (0.411); catalogued as rs1556833511, COSV63294502; called by muse, mutect2, varscan2
- MAGEB1 | c.689A>T p.Y230F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.819); catalogued as COSV66775446; called by muse, mutect2, varscan2
- MAPK1 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53185716; called by muse, mutect2
- MED13 | c.1355T>C p.I452T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV67262797; called by muse, mutect2, varscan2
- MED25 | c.1297G>A p.V433M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1287538303, COSV57203690; called by muse, mutect2, varscan2
- MLF2 | c.417G>C p.R139S | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV52570928; called by muse, mutect2, varscan2
- MNX1 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs779286203, COSV53317926; called by muse, mutect2, varscan2
- MORC4 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 65/100 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55240360; called by muse, mutect2, varscan2
- MTUS2 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.013); catalogued as COSV70914179; called by muse, mutect2, varscan2
- MUC16 | c.14828C>T p.P4943L | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.083); catalogued as COSV67456064; called by muse, mutect2, varscan2
- MUC16 | c.9364A>G p.T3122A | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs751051072, COSV67456066; called by muse, varscan2
- MUC17 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 541/791 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV60284236; called by muse, mutect2, varscan2
- MUC17 | c.4435C>T p.P1479S | Missense Mutation (SNP) | VAF 46/787 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV60284243; called by muse, mutect2
- MYF6 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV57351008; called by muse, mutect2, varscan2
- MYH7 | c.5562G>A p.T1854= | Splice Region (SNP) | VAF 26/50 reads (52%) | catalogued as rs368706722; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- NAB2 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55665814; called by muse, mutect2, varscan2
- NASP | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs370255034; called by muse, mutect2, varscan2
- NCOA1 | c.3715C>T p.P1239S | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV56040850; called by muse, mutect2, varscan2
- NCOR1 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as rs1387531900, COSV51965817; called by muse, mutect2, varscan2
- NDST3 | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV56614868, COSV56620722; called by muse, mutect2, varscan2
- NDST4 | c.2338G>A p.D780N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV52112464; called by muse, mutect2, varscan2
- NELL1 | c.1882C>T p.P628S | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV54247093; called by muse, mutect2, varscan2
- NELL2 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61571244, COSV61571447; called by muse, mutect2
- NFX1 | c.2871A>G p.K957= | Splice Region (SNP) | VAF 21/42 reads (50%) | catalogued as rs1355650392, COSV63196103; called by muse, mutect2, varscan2
- NINJ1 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs144669023; called by muse, mutect2, varscan2
- NKTR | c.3623C>T p.T1208I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV51770672; called by muse, mutect2, varscan2
- NOP56 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.168); catalogued as COSV61389278, COSV61390166; called by muse, mutect2, varscan2
- NPAS4 | c.1363C>T p.L455F | Missense Mutation (SNP) | VAF 41/236 reads (17%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1391815252, COSV60649410; called by muse, mutect2, varscan2
- NUP205 | c.4771C>G p.R1591G | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs768219930, COSV53657013, COSV53658998; called by muse, mutect2
- OR1L4 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 69/317 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52339979; called by muse, varscan2
- OR2C3 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV63574725; called by muse, mutect2, varscan2
- OR4P4 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV58921068; called by muse, mutect2, varscan2
- OR51B5 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100332562, COSV56175462; called by muse, mutect2, varscan2
- OR52R1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs200914402, COSV61887825; called by muse, mutect2
- OR5D14 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV59455721, COSV59456023; called by muse, mutect2, varscan2
- OR6C74 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV59605921, COSV59606182; called by muse, varscan2
- OR6C76 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.226); catalogued as COSV60388769; called by muse, mutect2, varscan2
- OR9Q1 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV59038758; called by muse, mutect2, varscan2
- OTOGL | c.3818C>T p.S1273F (on ENST00000547103; = p.S1264F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72005875; called by muse, mutect2, varscan2
- OTOL1 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs760999493, COSV60006374; called by muse, mutect2, varscan2
- P3H2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs575702697, COSV60020066; called by muse, mutect2, varscan2
- PCDHA5 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.219); catalogued as rs782365322, COSV65350853; called by muse, mutect2, varscan2
- PCLO | c.8236G>A p.D2746N | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs867757008, COSV61616448, COSV61625308; called by muse, mutect2, varscan2
- PEG3 | c.3330G>T p.E1110D | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as COSV55628587; called by muse, mutect2, varscan2
- PITPNM3 | c.2476A>C p.N826H | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.828); catalogued as COSV52593784; called by muse, mutect2, varscan2
- PIWIL2 | c.405G>T p.E135D | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV63250322; called by muse, mutect2, varscan2
- PLA2R1 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs770292851, COSV51776306; called by muse, mutect2
- PLB1 | c.1632G>A p.E544= | Splice Region (SNP) | VAF 26/69 reads (38%) | catalogued as COSV59822313; called by muse, mutect2, varscan2
- PLCXD3 | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.745); catalogued as COSV60606473; called by muse, mutect2, varscan2
- POLR3B | c.1282A>G p.R428G | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57277621; called by muse, mutect2, varscan2
- PPP6C | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65207354; called by muse, mutect2, varscan2
- PRDM10 | c.762+2T>G p.X254_splice | Splice Site (SNP) | VAF 33/111 reads (30%) | catalogued as COSV58800376; called by muse, mutect2, varscan2
- PRKD3 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV52211167; called by muse, mutect2, varscan2
- PRODH2 | c.620A>G p.N207S (on ENST00000301175; = p.N131S on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV56558816; called by muse, mutect2, varscan2
- PROM2 | c.2441G>A p.S814N | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV58297272; called by muse, mutect2, varscan2
- PRR23B | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.966); catalogued as COSV61493374; called by muse, mutect2, varscan2
- PRRG4 | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99141364; called by muse, mutect2, varscan2
- PTPRJ | c.1714C>T p.H572Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.703); catalogued as COSV69250525; called by muse, mutect2, varscan2
- RAD54L2 | c.4022C>T p.P1341L | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.299); catalogued as COSV56577607; called by muse, mutect2, varscan2
- RASGRF2 | c.2630C>T p.S877L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV54125068; called by muse, mutect2, varscan2
- RASSF9 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63433078; called by muse, mutect2, varscan2
- RBM25 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs1267296242, COSV56198992; called by muse, mutect2, varscan2
- RIMBP2 | c.2082G>C p.E694D | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55468785; called by muse, mutect2, varscan2
- RIPK4 | c.2005C>T p.R669C (on ENST00000352483; = p.R621C on NM_020639.3) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774992899, COSV60186389; called by muse, mutect2, varscan2
- RNF133 | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as COSV57356488; called by muse, mutect2, varscan2
- RNF214 | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs772228026, COSV100326803; called by muse, mutect2, varscan2
- RP1L1 | c.689T>G p.M230R | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV61444373; called by muse, mutect2
- RPTOR | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs201102317, COSV60806042; called by muse, mutect2, varscan2
- RTKN2 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs138538612; called by muse, mutect2, varscan2
- RYR1 | c.5815-1G>A p.X1939_splice | Splice Site (SNP) | VAF 15/103 reads (15%) | catalogued as COSV62093508; called by muse, mutect2, varscan2
- S100A9 | c.233A>T p.E78V | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64199585; called by muse, mutect2, varscan2
- SAMD9 | c.1658G>A p.R553K | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66073966; called by muse, mutect2
- SATB2 | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV53480229; called by muse, mutect2, varscan2
- SATB2 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV53480240; called by muse, mutect2, varscan2
- SCN10A | c.5279C>T p.T1760I | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV71860689; called by muse, mutect2, varscan2
- SCNN1A | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.999); catalogued as COSV57434894; called by muse, mutect2, varscan2
- SCUBE2 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs765365843, COSV58540609; called by muse, mutect2, varscan2
- SDR42E1 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as rs759669365, COSV61093955; called by muse, mutect2, varscan2
- SH3BP4 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV60643280; called by muse, mutect2, varscan2
- SIPA1L1 | c.2230C>T p.P744S | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62169075; called by muse, mutect2, varscan2
- SLC14A1 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV58931243; called by muse, mutect2, varscan2
- SLC16A6 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59176590; called by muse, mutect2, varscan2
- SLC22A2 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs199783132, COSV65265852; called by muse, mutect2, varscan2
- SLC2A12 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51598598; called by muse, mutect2, varscan2
- SLCO4C1 | c.1703G>A p.G568E | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100194388, COSV60513691; called by muse, mutect2, varscan2
- SMC1B | c.2368C>T p.R790C | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs766164339, COSV100663039, COSV62529052; called by muse, mutect2, varscan2
- SNRPN | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 60/293 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV57595148; called by muse, mutect2, varscan2
- SNX21 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as rs1484903535; called by muse, mutect2, varscan2
- SQSTM1 | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757212984, CM041449, COSV52972344; called by muse, mutect2, varscan2
- SS18 | c.1021C>T p.P341S (on ENST00000415083 / NM_001007559.3; = p.P310S on NM_005637.3) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.031); catalogued as rs371114958, COSV52260033; called by muse, mutect2, varscan2
- STAT5A | c.1064T>C p.L355P | Missense Mutation (SNP) | VAF 72/141 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61806110; called by muse, mutect2, varscan2
- SULT2B1 | c.883C>T p.R295C (on ENST00000201586 / NM_177973.2; = p.R280C on NM_004605.2) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs920026531, COSV52374955; called by muse, mutect2
- SVEP1 | c.1124T>C p.L375P | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs1330898764, COSV57033032; called by muse, mutect2, varscan2
- SVIL | c.2538G>A p.M846I (on ENST00000355867 / NM_021738.3; = p.M420I on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV63441844; called by muse, mutect2, varscan2
- SYMPK | c.174C>T p.V58= | Splice Region (SNP) | VAF 13/108 reads (12%) | catalogued as COSV55610580; called by muse, mutect2, varscan2
- SYTL2 | c.1093A>G p.K365E | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV60357540; called by muse, mutect2, varscan2
- TADA3 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV57332545; called by muse, mutect2, varscan2
- TAF4 | c.1720C>A p.R574S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.81); catalogued as COSV53336184, COSV53340372; called by muse, mutect2, varscan2
- TAOK2 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.441); catalogued as rs146662869; called by muse, mutect2, varscan2
- TEK | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 134/213 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV66228027; called by muse, mutect2, varscan2
- TEKT3 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 85/144 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs1166921556, COSV58626443; called by muse, mutect2, varscan2
- TENM2 | c.1403G>A p.R468K (on ENST00000518659 / NM_001122679.2; = p.R236K on NM_001080428.3) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV69126898; called by muse, mutect2, varscan2
- TEX11 | c.2087G>A p.R696K (on ENST00000344304; = p.R681K on NM_031276.3) | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV60227831; called by muse, mutect2, varscan2
- TEX13A | c.1052G>A p.R351K | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs368716285, COSV61149542; called by muse, mutect2, varscan2
- TGM1 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.137); catalogued as rs138885883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TIGD3 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV52888408; called by muse, mutect2, varscan2
- TLN1 | c.6401C>T p.A2134V | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV59205247; called by muse, mutect2, varscan2
- TMED9 | c.664A>G p.M222V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs11545862, COSV50352835; called by muse, mutect2, varscan2
- TMEM185A | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 86/129 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV57559109; called by muse, mutect2, varscan2
- TMX3 | c.1036-1G>A p.X346_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV55184438; called by muse, mutect2, varscan2
- TRHDE | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV53838762; called by muse, mutect2
- TRMT9B | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71600263; called by muse, mutect2, varscan2
- TRPV5 | c.1779G>A p.W593* | Nonsense Mutation (SNP) | VAF 16/172 reads (9%) | catalogued as COSV54684311; called by muse, mutect2
- TRRAP | c.3119C>T p.P1040L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as COSV62841912; called by muse, mutect2
- TTBK1 | c.929G>T p.W310L | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52489299; called by muse, mutect2, varscan2
- TTN | c.11593G>A p.E3865K (on ENST00000591111; = p.E3819K on NM_003319.4) | Missense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as rs569444314, COSV100613632, COSV59958575; called by muse, mutect2, varscan2
- UNC13C | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs867561604, COSV52857466; called by muse, mutect2, varscan2
- UPB1 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs372357415; called by muse, mutect2, varscan2
- USP4 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs536981448, COSV55535875; called by muse, mutect2, varscan2
- USP40 | c.2906C>T p.S969F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as COSV52478975; called by muse, mutect2, varscan2
- UXS1 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV51676337; called by muse, mutect2, varscan2
- VWA3A | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV55389535, COSV55394512; called by muse, mutect2, varscan2
- VWA3B | c.3062G>A p.G1021E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV68241779; called by muse, mutect2
- VWA8 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55694735; called by muse, mutect2, varscan2
- WAS | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 32/63 reads (51%) | catalogued as CM129446, COSV64996745; called by muse, mutect2, varscan2
- ZBED1 | c.509C>A p.T170N | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as rs769216157; called by muse, mutect2, varscan2
- ZNF180 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV55419864; called by muse, mutect2, varscan2
- ZNF574 | c.1648C>T p.P550S | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV55902515; called by muse, mutect2, varscan2
- ZNF689 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54908021; called by muse, mutect2, varscan2
- ZNF705D | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1465537837, COSV67956302; called by muse, mutect2, varscan2
- ZSCAN32 | c.946C>T p.H316Y (on ENST00000396846; = p.H337Y on NM_017810.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59234650; called by muse, mutect2, varscan2
- ZSCAN5B | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100748552, COSV62838810; called by muse, mutect2, varscan2
- ATP7B | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DNAH5 | c.5883-2_5896del p.X1961_splice | Splice Site (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel
- GOT1 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV4-31 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 117/279 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- LTA | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCGF2 | c.316+1G>A p.X106_splice | Splice Site (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- PIK3C2A | c.40_90del p.P14_E30del | In Frame Del (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel
- PRRG4 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- REPIN1 | c.1618G>T p.D540Y | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- TRAV17 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- ABL1 | c.1491C>T p.F497= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as COSV59328307; called by muse, mutect2, varscan2
- ACRV1 | c.291G>A p.E97= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV59754700; called by muse, mutect2, varscan2
- AFMID | c.753C>T p.F251= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV59975676; called by muse, mutect2
- ANKAR | c.3990G>A p.L1330= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV51462082; called by muse, mutect2, varscan2
- ANO1 | c.2355C>T p.I785= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs1331630788, COSV62444709; called by muse, mutect2, varscan2
- AOAH | c.1530G>A p.Q510= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs1204021444, COSV51738168; called by muse, mutect2, varscan2
- ASH1L | c.7887C>T p.D2629= (on ENST00000368346 / NM_001366177.2; = p.D2624= on NM_018489.3) | Silent (SNP) | VAF 40/266 reads (15%) | catalogued as COSV64206739; called by muse, mutect2, varscan2
- AXDND1 | c.2179C>T p.L727= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV62641118; called by muse, mutect2, varscan2
- BMP3 | c.345C>T p.I115= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV51082342; called by muse, mutect2, varscan2
- BPIFB1 | c.757T>C p.L253= | Silent (SNP) | VAF 32/181 reads (18%) | catalogued as COSV53605838; called by muse, mutect2, varscan2
- BRINP1 | c.2139G>A p.G713= | Silent (SNP) | VAF 44/87 reads (51%) | catalogued as COSV56296505, COSV56307061; called by muse, mutect2, varscan2
- CACNA1C | c.2982G>A p.V994= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV59707355; called by muse, mutect2, varscan2
- CAMK2A | c.84A>G p.R28= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as COSV62245795; called by muse, mutect2, varscan2
- CCDC141 | c.2664G>A p.E888= | Silent (SNP) | VAF 110/420 reads (26%) | catalogued as COSV55371336; called by muse, mutect2, varscan2
- CD163 | c.495G>A p.G165= | Silent (SNP) | VAF 93/340 reads (27%) | catalogued as rs766179361, COSV63129001; called by muse, mutect2, varscan2
- COMT | c.177C>T p.I59= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs1342715506, COSV52889484; called by muse, mutect2, varscan2
- CRNN | c.906G>A p.V302= | Silent (SNP) | VAF 204/413 reads (49%) | catalogued as COSV55121363; called by muse, mutect2, varscan2
- CRYBG2 | c.1371C>T p.P457= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV57485060; called by muse, mutect2, varscan2
- DDC | c.469C>T p.L157= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs537713577, COSV63564600; called by muse, mutect2, varscan2
- DMGDH | c.216G>A p.G72= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV54862251; called by muse, mutect2, varscan2
- DNAH17 | c.6246G>A p.R2082= | Silent (SNP) | VAF 89/205 reads (43%) | catalogued as COSV67751685; called by muse, mutect2, varscan2
- DNAH5 | c.10053G>A p.Q3351= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV54201371, COSV54250907; called by muse, mutect2, varscan2
- DNAH5 | c.7962T>C p.V2654= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV54214898; called by muse, mutect2, varscan2
- DNAH5 | c.6588G>A p.E2196= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs1268685266, COSV54214908; called by muse, mutect2, varscan2
- DNAH5 | c.1575C>T p.F525= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs755393698, COSV54214934; called by muse, mutect2, varscan2
- DNAH7 | c.11256C>T p.V3752= | Silent (SNP) | VAF 81/272 reads (30%) | catalogued as rs764238805, COSV56758044; called by muse, mutect2, varscan2
- DNAH8 | c.6651C>T p.S2217= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs775873897, COSV59424278; called by muse, mutect2, varscan2
- DNAJC13 | c.4203T>G p.T1401= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV53448119; called by muse, mutect2, varscan2
- DPF1 | c.825C>T p.S275= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as rs764208520, COSV62792465; called by muse, mutect2, varscan2
- EEF2K | c.645C>T p.I215= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs780591039, COSV53780225; called by muse, mutect2, varscan2
- ELAVL2 | c.429G>A p.Q143= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as rs767310033, COSV56359806; called by muse, mutect2, varscan2
- ELMO1 | c.336G>A p.R112= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as COSV60300231; called by muse, mutect2, varscan2
- EPDR1 | c.414C>T p.S138= | Silent (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2
- FBH1 | c.1167G>T p.V389= (on ENST00000362091 / NM_178150.3; = p.V440= on NM_032807.4) | Silent (SNP) | VAF 65/153 reads (42%) | catalogued as COSV62982126; called by muse, mutect2, varscan2
- FBXO27 | c.831C>T p.I277= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as rs1020876736, COSV53071954; called by muse, mutect2, varscan2
- FCRL2 | c.258A>G p.G86= | Silent (SNP) | VAF 38/112 reads (34%) | catalogued as COSV63833174; called by muse, mutect2, varscan2
- FCRL4 | c.1311C>T p.S437= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV54861187; called by muse, mutect2, varscan2
- FEM1C | c.1377A>G p.L459= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs941164289; called by muse, mutect2, varscan2
- FLNB | c.1401C>T p.V467= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV55874726; called by muse, mutect2, varscan2
- FMO5 | c.1488G>A p.R496= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV54205443; called by muse, mutect2, varscan2
- FNTB | c.663C>T p.L221= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV55760718; called by muse, mutect2, varscan2
- FOXA2 | c.186C>T p.S62= (on ENST00000377115 / NM_153675.3; = p.S68= on NM_021784.5) | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as COSV65795963; called by muse, mutect2, varscan2
- FUCA1 | c.1221C>G p.V407= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV65698909; called by muse, varscan2
- GCSAML | c.342G>A p.R114= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV63577425; called by muse, mutect2, varscan2
- GIMAP8 | c.1680G>A p.A560= | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as rs1203845409, COSV56229956; called by muse, mutect2
- GOT1 | c.774C>T p.S258= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV65147717; called by muse, mutect2, varscan2
- HIF3A | c.426G>A p.Q142= (on ENST00000377670 / NM_152795.4; = p.Q73= on NM_022462.4) | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as COSV52196934; called by muse, varscan2
- HNRNPA1L2 | c.360C>T p.H120= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs1304058939, COSV61255114; called by muse, mutect2, varscan2
- IGFBP5 | c.378G>A p.E126= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs1289132353, COSV52082344; called by muse, mutect2, varscan2
- IL1F10 | c.459G>A p.*153= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV61750470; called by muse, mutect2, varscan2
- ILDR1 | c.855C>T p.V285= (on ENST00000344209 / NM_001199799.2; = p.V241= on NM_175924.4) | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV56549076; called by muse, mutect2, varscan2
- KCNF1 | c.465C>T p.D155= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs1417292098, COSV54462632; called by muse, varscan2
- KIAA1217 | c.3195G>A p.T1065= | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as rs1278335671, COSV56814803; called by muse, mutect2, varscan2
- KIF17 | c.2127C>T p.P709= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV56117171; called by muse, mutect2, varscan2
- KIF3C | c.954G>A p.R318= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV53098615; called by muse, mutect2, varscan2
- KLHDC7A | c.1591C>A p.R531= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV68769360; called by muse, mutect2, varscan2
- KLKB1 | c.1452C>T p.I484= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1340485490, COSV52994761; called by muse, mutect2, varscan2
- LCK | c.975G>A p.V325= | Silent (SNP) | VAF 50/284 reads (18%) | catalogued as COSV60739447; called by muse, mutect2, varscan2
- MACROD2 | c.483T>C p.L161= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV53965345; called by muse, mutect2, varscan2
- MAML3 | c.1681C>T p.L561= | Silent (SNP) | VAF 90/310 reads (29%) | catalogued as COSV59072792; called by muse, mutect2, varscan2
- MSL2 | c.423G>A p.E141= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV53861562; called by muse, mutect2, varscan2
- MYO16 | c.2925G>A p.K975= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV51784974; called by muse, mutect2, varscan2
- MYO18B | c.3486G>A p.R1162= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV59130062; called by muse, mutect2, varscan2
- NIPBL | c.4203A>T p.L1401= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV56947602; called by muse, mutect2, varscan2
- NSD2 | c.960C>T p.A320= | Silent (SNP) | VAF 31/61 reads (51%) | catalogued as rs201203687, COSV56388780; called by muse, mutect2, varscan2
- OR10X1 | c.357C>T p.F119= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV63767173; called by muse, mutect2, varscan2
- OR1Q1 | c.753C>T p.F251= | Silent (SNP) | VAF 55/100 reads (55%) | catalogued as COSV52917586; called by muse, mutect2, varscan2
- OR2A2 | c.801G>A p.E267= | Silent (SNP) | VAF 230/373 reads (62%) | catalogued as COSV68871322; called by muse, mutect2
- OR4D11 | c.903G>A p.L301= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs116174674, COSV57585210; called by muse, mutect2, varscan2
- OR52E6 | c.876C>T p.I292= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV61431660, COSV61431707; called by muse, mutect2, varscan2
- OR7E24 | c.153C>T p.S51= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as COSV101509688, COSV71702121; called by muse, mutect2, varscan2
- OSMR | c.1077G>A p.R359= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs868747449, COSV57083298; called by muse, mutect2, varscan2
- PCDHGA5 | c.2283G>T p.A761= | Silent (SNP) | VAF 73/191 reads (38%) | catalogued as COSV53920567, COSV53921770; called by muse, mutect2, varscan2
- PCDHGB6 | c.429C>T p.F143= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV53899918; called by muse, mutect2, varscan2
- PLIN1 | c.576C>T p.L192= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs750205728, COSV55583213; called by muse, mutect2, varscan2
- PPARGC1B | c.1993C>T p.L665= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs936108124, COSV58528012; called by muse, mutect2, varscan2
- PRAMEF4 | c.600C>T p.I200= | Silent (SNP) | VAF 25/187 reads (13%) | catalogued as COSV99339541; called by muse, mutect2, varscan2
- RCOR3 | c.690A>T p.A230= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV65365335; called by muse, mutect2, varscan2
- RHOBTB2 | c.486C>T p.P162= | Silent (SNP) | VAF 77/117 reads (66%) | catalogued as COSV52570235; called by muse, mutect2, varscan2
- SALL3 | c.3162C>T p.S1054= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs746604663, COSV73305906; called by muse, mutect2, varscan2
- SF3B1 | c.2907A>G p.K969= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV59211054; called by muse, mutect2, varscan2
- SHPK | c.903G>A p.T301= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs978688211, COSV56648658, COSV56650179; called by muse, mutect2, varscan2
- SIK3 | c.1015C>T p.L339= (on ENST00000445177 / NM_001366686.2; = p.L345= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as COSV52611627; called by muse, mutect2, varscan2
- SLC1A3 | c.222C>T p.S74= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV54315223; called by muse, mutect2, varscan2
- SLC22A5 | c.561G>A p.Q187= | Silent (SNP) | VAF 53/172 reads (31%) | catalogued as COSV55372360; called by muse, mutect2, varscan2
- SLC39A5 | c.1248C>T p.T416= | Silent (SNP) | VAF 158/390 reads (41%) | catalogued as COSV57191121; called by muse, mutect2, varscan2
- SLC45A1 | c.1626C>T p.L542= | Silent (SNP) | VAF 33/119 reads (28%) | catalogued as COSV57094174; called by muse, mutect2, varscan2
- SLC9C2 | c.1857A>C p.I619= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV62944787; called by muse, mutect2, varscan2
- SMYD3 | c.1119G>A p.V373= (on ENST00000490107 / NM_001375962.1; = p.V314= on NM_022743.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV63626281; called by muse, mutect2, varscan2
- SNRNP200 | c.5187C>T p.D1729= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as COSV60488535; called by muse, mutect2, varscan2
- SNX21 | c.813C>T p.A271= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- SPHKAP | c.2838G>A p.A946= | Silent (SNP) | VAF 55/142 reads (39%) | catalogued as rs763319527, COSV60872113; called by muse, mutect2, varscan2
- SPTA1 | c.2352C>T p.T784= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV63751084; called by muse, mutect2, varscan2
- SYT4 | c.1149C>T p.S383= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs1489254774, COSV54899389, COSV99673397; called by muse, mutect2, varscan2
- TAF15 | c.1020T>C p.Y340= (on ENST00000605844 / NM_139215.3; = p.Y337= on NM_003487.4) | Silent (SNP) | VAF 102/173 reads (59%) | catalogued as rs777176470; called by muse, mutect2, varscan2
- THADA | c.2856C>T p.L952= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV57680074; called by muse, mutect2, varscan2
- TINAGL1 | c.363C>T p.N121= | Silent (SNP) | VAF 42/142 reads (30%) | catalogued as COSV54698701; called by muse, mutect2, varscan2
- TMEM132D | c.2856C>T p.F952= | Silent (SNP) | VAF 42/163 reads (26%) | catalogued as rs375992244, COSV67160529; called by muse, mutect2, varscan2
- TMEM150B | c.330G>A p.K110= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV58593441, COSV58594191; called by muse, mutect2, varscan2
- TRIM7 | c.978G>A p.K326= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV51241320; called by muse, mutect2, varscan2
- TRPM7 | c.3765G>A p.S1255= | Silent (SNP) | VAF 23/187 reads (12%) | catalogued as rs765622293, COSV57915065; called by muse, mutect2, varscan2
- TSHR | c.2244C>T p.T748= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV53317301; called by muse, mutect2, varscan2
- TXNDC15 | c.697C>T p.L233= | Silent (SNP) | VAF 26/147 reads (18%) | catalogued as COSV64379216; called by muse, mutect2, varscan2
- UGT2B4 | c.462C>T p.F154= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs762873692, COSV59316210; called by muse, mutect2, varscan2
- UNC13C | c.2455C>T p.L819= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV52857430; called by muse, mutect2, varscan2
- XIRP2 | c.5331G>A p.V1777= (on ENST00000628543; = p.V1952= on NM_152381.6) | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV54691162; called by muse, mutect2, varscan2
- ZBED1 | c.510C>T p.T170= | Silent (SNP) | VAF 27/218 reads (12%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.2166G>A p.Q722= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV60156164; called by muse, mutect2, varscan2
- ZNF195 | c.1104C>T p.S368= (on ENST00000399602 / NM_001130520.3; = p.S296= on NM_007152.5) | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as rs373253796, COSV50002682; called by muse, mutect2, varscan2
- ZNF221 | c.165C>T p.Y55= | Silent (SNP) | VAF 36/320 reads (11%) | catalogued as rs1223916931, COSV52108738; called by muse, mutect2
- ZNF385B | c.837G>A p.K279= | Silent (SNP) | VAF 39/145 reads (27%) | catalogued as COSV61176595; called by muse, mutect2, varscan2
- ZNF600 | c.1773C>T p.F591= | Silent (SNP) | VAF 27/246 reads (11%) | catalogued as rs151077073; called by muse, mutect2, varscan2
- ZSWIM3 | c.780C>T p.T260= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV54846234; called by muse, mutect2, varscan2
- ZXDC | c.939C>G p.A313= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV60446209; called by muse, mutect2, varscan2
- AC244258.1 | n.437G>A | RNA (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73825372 C>T | 5'Flank (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- BTD | c.-318C>T | 5'UTR (SNP) | VAF 18/62 reads (29%) | catalogued as COSV57728683; called by muse, mutect2, varscan2
- CR2 | c.1979-112G>A | Intron (SNP) | VAF 34/190 reads (18%) | catalogued as COSV65506230; called by muse, mutect2, varscan2
- DCHS2 | n.3570C>T | RNA (SNP) | VAF 53/136 reads (39%) | catalogued as COSV59720981; called by muse, mutect2, varscan2
- DENND1B | c.83-20558G>A | Intron (SNP) | VAF 5/54 reads (9%) | catalogued as COSV99345231; called by muse, mutect2, varscan2
- NDE1 | c.*35C>T | 3'UTR (SNP) | VAF 17/59 reads (29%) | catalogued as rs1376881641, COSV55547932; called by muse, mutect2, varscan2
- OR2U1P | n.300C>T | RNA (SNP) | VAF 68/241 reads (28%) | called by muse, mutect2, varscan2
- PRR12 | c.51+561C>T | Intron (SNP) | VAF 4/67 reads (6%) | catalogued as rs1035369299, COSV69817123; called by muse, mutect2
- SNORD116-26 | n.40A>G | RNA (SNP) | VAF 27/102 reads (26%) | catalogued as rs760515332; called by muse, mutect2, varscan2
- TTN | c.10360+4919C>T | Intron (SNP) | VAF 19/53 reads (36%) | catalogued as COSV60179573, COSV60181801; called by muse, mutect2, varscan2
